TCGA case TCGA-SN-A6IS — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: BLN - Baylor. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7b411b6f-a273-4ea0-b5c8-637520f1fe5f

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 26 years; Year of birth: 1986; Vital status: Alive.

Diagnoses (1)
1. Mixed germ cell tumor: ICD-O-3 morphology code: 9085/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 26.3 years (9,618 days); Year of diagnosis: 2013; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical T: T1; AJCC clinical N: NX; AJCC clinical M: M0; AJCC clinical stage: Stage IS; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 496 days (1.4 years); Ajcc serum tumor markers: S1.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 148 days; Disease response: Tumor Free.
- Days to follow up: 496 days (1.4 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -7: Lactate Dehydrogenase 240; Alpha Fetoprotein 3.3; Human Chorionic Gonadotropin 1708.
- Day 55: Lactate Dehydrogenase 165; Alpha Fetoprotein 3; Human Chorionic Gonadotropin 1.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Conceived 1 or more children by natural conception.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SN-A6IS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-SN-A6IS-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 24; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-SN-A6IS-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SN-A6IS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History fertility: Fathered > or = 1 child by natural conception; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Stage record: AJCC pathologic tumor stage: IS.
- Primary pathology: Submitted tumor site: Testes; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology 1: Histologic diagnosis: Seminoma, NOS; Histologic diagnosis percent: 85.
- Primary pathology, Histology list, Histology 2: Histologic diagnosis: Non-Seminoma, Teratoma (Mature); Histologic diagnosis percent: 15.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 240; Pre orchi hcg: 1708; Pre orchi afp: 3.3.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 165; Post orchi hcg: 1; Post orchi afp: 3.0.
- Primary pathology, Molecular test result list: Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal.
- Follow-up form: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 496 days; disease-specific survival: no event (censored), 496 days; disease-free interval: no event (censored), 496 days; progression-free interval: no event (censored), 496 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SN-A6IS-01A-11D-A434-01): tumor purity 0.51, ploidy 2.98, whole-genome doublings 1.
